Somatic mutation profile of tumor specimen TCGA-63-A5MV-01A (aliquot TCGA-63-A5MV-01A-21D-A26M-08) from TCGA case TCGA-63-A5MV, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-A5MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d2564e1-d9bd-4e52-bdb8-6f637fe344a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MV-10A (Blood Derived Normal), aliquot TCGA-63-A5MV-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cd71a18-ae9f-4587-8b1b-fc35b00b2002

The open-access MAF lists 127 somatic variants for this specimen: 95 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 2, 3'UTR 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACKR2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1420471671, COSV99825482; called by muse, mutect2, varscan2
- ACYP2 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1235936508, COSV100336540; called by muse, mutect2
- ADAMTS10 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.442); catalogued as rs140455325; called by muse, mutect2, varscan2
- ADAMTS15 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777723828, COSV100143333; called by muse, mutect2
- AGTPBP1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV100429656; called by muse, mutect2, varscan2
- AHCTF1 | c.2236G>C p.E746Q (on ENST00000366508; = p.E720Q on NM_015446.5) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV58247691, COSV58250865; called by muse, mutect2, varscan2
- AP3D1 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100642633; called by muse, mutect2, varscan2
- APBA2 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258151; called by muse, mutect2, varscan2
- ARHGEF1 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100528969; called by muse, mutect2, varscan2
- ARSF | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.166); catalogued as COSV63840412; called by muse, mutect2, varscan2
- ASCC3 | c.6283A>G p.K2095E | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV100976426; called by muse, mutect2
- BRD2 | c.474C>A p.P158= | Splice Region (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100875655; called by muse, mutect2, varscan2
- CACNA2D1 | c.2972G>T p.S991I (on ENST00000356253 / NM_001366867.1; = p.S979I on NM_000722.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100666549; called by muse, mutect2
- CAMKK2 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100242879; called by muse, mutect2, varscan2
- CCDC172 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.025); catalogued as rs866518323, COSV100319714, COSV100319743; called by muse, mutect2, varscan2
- CDH10 | c.1748C>A p.T583N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100051201, COSV52591707; called by muse, mutect2, varscan2
- CDH7 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542177, COSV100542376; called by muse, mutect2, varscan2
- CEP250 | c.6453G>C p.E2151D | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100698896; called by muse, mutect2, varscan2
- CES1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100828650; called by muse, mutect2, varscan2
- CHD8 | c.1795G>A p.E599K (on ENST00000646647 / NM_001170629.2; = p.E320K on NM_020920.4) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV67870281; called by muse, mutect2, varscan2
- CNOT1 | c.2493G>T p.Q831H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as COSV99800030; called by muse, mutect2, varscan2
- CTDP1 | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99310470; called by muse, mutect2, varscan2
- CTNNAL1 | c.1755G>C p.K585N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100336498; called by muse, mutect2, varscan2
- DEFB127 | c.170T>A p.I57N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV101213823; called by muse, mutect2, varscan2
- DEFB129 | c.154A>C p.K52Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV99857426; called by muse, mutect2, varscan2
- EDAR | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV99303492; called by muse, mutect2, varscan2
- FCRL2 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100829895; called by muse, mutect2, varscan2
- GLB1L | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs377401220, COSV99850499; called by muse, mutect2, varscan2
- GRID2 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1204912375, COSV99940170; called by muse, mutect2
- GRM7 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100736236; called by muse, mutect2, varscan2
- H2BC17 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV58152307; called by muse, mutect2, varscan2
- HS2ST1 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777666, COSV100777723; called by muse, mutect2
- IGF2R | c.1229T>A p.L410H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807295; called by muse, mutect2
- INF2 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as rs1340612270, COSV99383819; called by muse, mutect2
- INTS10 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101208676; called by muse, mutect2
- KLHL4 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100909485, COSV100910100; called by muse, mutect2
- KRTAP10-12 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 45/167 reads (27%) | catalogued as rs782110806, COSV100553232; called by muse, mutect2, varscan2
- LIMCH1 | c.283A>T p.K95* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100573749; called by muse, mutect2, varscan2
- LRP8 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100036377; called by muse, mutect2, varscan2
- LRRC52 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs374982726; called by muse, mutect2
- LRRIQ1 | c.3982C>A p.Q1328K | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101280116; called by muse, mutect2, varscan2
- MAP9 | c.1096A>G p.N366D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV100250869; called by muse, mutect2
- MARCHF2 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs200909043, COSV99294739; called by muse, mutect2, varscan2
- MMP16 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99687749; called by muse, mutect2, varscan2
- MRPL14 | c.71+1G>T p.X24_splice | Splice Site (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100921038; called by muse, mutect2, varscan2
- MUC16 | c.10880C>A p.S3627Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101199618; called by muse, mutect2
- MUC17 | c.10655G>T p.S3552I | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as COSV100072937; called by muse, mutect2, varscan2
- MYDGF | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV99501626; called by muse, mutect2
- NFKBIZ | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100397030; called by muse, mutect2
- NLRP14 | c.764T>A p.L255* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV100204890; called by muse, mutect2, varscan2
- NUDCD1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99517070; called by muse, mutect2, varscan2
- NUTM2F | c.1175del p.P392Lfs*43 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs771183172; called by mutect2, varscan2
- OR5H15 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV100736655; called by muse, mutect2, varscan2
- PAPPA2 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100866758; called by muse, mutect2, varscan2
- PBX1 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100905035; called by muse, mutect2, varscan2
- PCDHB12 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53401205, COSV99507167; called by muse, mutect2, varscan2
- PCDHGA2 | c.1279G>T p.G427* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53935645, COSV99536815; called by muse, mutect2, varscan2
- PCDHGB2 | c.1606G>C p.D536H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs564226347, COSV53945949, COSV99536821; called by muse, mutect2, varscan2
- PDE6B | c.2162C>G p.A721G | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55330925, COSV99727407; called by muse, mutect2, varscan2
- PER2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99611886; called by muse, mutect2, varscan2
- PGK2 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.226); catalogued as COSV100505449, COSV99079917; called by muse, mutect2, varscan2
- PIKFYVE | c.4407A>T p.Q1469H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100010548; called by muse, mutect2, varscan2
- PLCH1 | c.5042G>C p.S1681T (on ENST00000340059 / NM_001130960.2; = p.S1673T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); catalogued as COSV100396639; called by muse, mutect2
- PSME4 | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV101122460; called by muse, mutect2, varscan2
- PSTPIP2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV101297349; called by mutect2, varscan2
- RNF213 | c.2210+1G>C p.X737_splice | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100173257, COSV100173407; called by muse, mutect2, varscan2
- SCN2A | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as rs1553569828, COSV99331354; called by muse, mutect2, varscan2
- SH2D7 | c.1165C>A p.H389N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99363213; called by muse, mutect2, varscan2
- SLC26A9 | c.1096A>G p.N366D | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100536312; called by muse, mutect2, varscan2
- SLC52A2 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100095682; called by muse, mutect2, varscan2
- SPTBN2 | c.1951G>C p.G651R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); catalogued as COSV100019115; called by muse, mutect2
- SPTBN4 | c.3596A>T p.H1199L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV100150716; called by muse, mutect2, varscan2
- SYTL5 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99937158; called by muse, mutect2, varscan2
- TADA3 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99809481; called by muse, mutect2, varscan2
- TBX2 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV99538820; called by muse, mutect2, varscan2
- TNR | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99689251; called by muse, mutect2, varscan2
- TP53 | c.165del p.E56Kfs*67 | Frame Shift Del (DEL) | VAF 57/221 reads (26%) | catalogued as COSV53293945; called by mutect2, pindel, varscan2
- TPH2 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV100422035; called by muse, mutect2, varscan2
- TRIM49 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs866997358, COSV100316023; called by muse, mutect2, varscan2
- TSEN34 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs769338809, COSV55477442; called by muse, mutect2, varscan2
- TTLL6 | c.2336A>G p.K779R (on ENST00000393382 / NM_001130918.3; = p.K472R on NM_173623.3) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.149); catalogued as COSV100938102; called by muse, mutect2, varscan2
- TTN | c.79961C>A p.P26654Q (on ENST00000591111; = p.P19230Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100609980; called by muse, mutect2, varscan2
- TTN | c.17612G>A p.S5871N (on ENST00000591111; = p.S4944N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV100609982; called by muse, mutect2, varscan2
- UGT2B10 | c.741G>T p.E247D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV99608235; called by muse, mutect2, varscan2
- VWA2 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs374060724; called by muse, mutect2, varscan2
- WDFY3 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99883228; called by muse, varscan2
- WDR88 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201739777, COSV100866412, COSV63452513; called by muse, mutect2, varscan2
- XIRP1 | c.3127C>G p.P1043A | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100453579; called by muse, mutect2, varscan2
- XKR4 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100532336; called by muse, mutect2, varscan2
- ZNF160 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100762315; called by muse, mutect2, varscan2
- ZNF20 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503029; called by muse, mutect2, varscan2
- ZNF239 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021785; called by muse, mutect2, varscan2
- ZNF787 | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs756935897, COSV99555493; called by muse, mutect2, varscan2
- TIGD6 | c.867_869del p.N290del | In Frame Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- ZNF770 | c.1418del p.K473Rfs*18 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel
- ADAMTS5 | c.2643G>T p.T881= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99537494; called by muse, mutect2, varscan2
- ADGRB3 | c.201T>C p.Y67= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1213082897, COSV101000476; called by muse, mutect2, varscan2
- ATRNL1 | c.2523C>A p.P841= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100370365; called by muse, mutect2, varscan2
- CNTFR | c.918G>C p.P306= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100667541, COSV100667610; called by muse, mutect2, varscan2
- DEFB127 | c.171C>A p.I57= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV101213825, COSV66688895; called by muse, mutect2, varscan2
- EDIL3 | c.864C>T p.P288= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99676088; called by muse, mutect2, varscan2
- FAM83C | c.1623A>G p.P541= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1009840072, COSV100981557; called by muse, mutect2, varscan2
- FRAS1 | c.11691G>T p.A3897= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53590210, COSV99351236; called by muse, mutect2, varscan2
- GP6 | c.882G>C p.R294= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100117484; called by muse, mutect2
- GPR82 | c.732C>T p.Y244= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1477368628, COSV100220573; called by muse, mutect2, varscan2
- GRIK3 | c.2148G>A p.S716= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs746809134, COSV100901891; called by muse, mutect2, varscan2
- ICE1 | c.4887G>T p.G1629= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as COSV99664562; called by muse, mutect2, varscan2
- IGKV1-6 | c.201G>A p.K67= | Silent (SNP) | VAF 30/173 reads (17%) | catalogued as rs193170199; called by muse, mutect2, varscan2
- KANSL3 | c.2262C>A p.L754= (on ENST00000666923 / NM_001349262.2; = p.L728= on NM_001115016.3) | Silent (SNP) | VAF 7/149 reads (5%) | catalogued as COSV100831077; called by muse, mutect2
- KRT79 | c.576G>A p.E192= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs772953032, COSV100398417; called by muse, mutect2, varscan2
- LTBP4 | c.1197A>G p.Q399= (on ENST00000308370 / NM_001042544.1; = p.Q362= on NM_003573.2) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs773173450, COSV99190922; called by muse, mutect2, varscan2
- MMRN2 | c.1338G>A p.L446= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100922557; called by muse, mutect2, varscan2
- MS4A12 | c.18A>C p.P6= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99188778; called by muse, mutect2, varscan2
- NPHS1 | c.483G>C p.V161= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100799788; called by muse, mutect2, varscan2
- OVGP1 | c.843G>T p.A281= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV100868112; called by muse, mutect2, varscan2
- PCDHGA3 | c.186C>T p.R62= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as rs1160510110, COSV99536817; called by muse, mutect2, varscan2
- PKHD1L1 | c.2940T>C p.C980= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV101006020; called by muse, mutect2
- PRG4 | c.3360C>G p.P1120= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs376627984; called by muse, mutect2
- RTL3 | c.1236C>A p.P412= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100329737; called by muse, mutect2, varscan2
- SENP7 | c.2544A>G p.K848= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100053016; called by muse, mutect2, varscan2
- SLIT3 | c.720A>T p.T240= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs761204545, COSV100267074; called by muse, mutect2, varscan2
- STK26 | c.531T>C p.N177= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs142833022, COSV100688680; called by muse, mutect2, varscan2
- TACR2 | c.87C>T p.P29= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100964801; called by muse, mutect2, varscan2
- TMEM130 | c.765C>A p.T255= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100228704; called by muse, mutect2, varscan2
- U2SURP | c.3030C>T p.S1010= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101204446; called by muse, mutect2, varscan2
- SNORD115-19 | n.55C>G | RNA (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2, varscan2
- STATH | c.*2A>G | 3'UTR (SNP) | VAF 15/65 reads (23%) | catalogued as rs1030787522, COSV99887208; called by muse, mutect2, varscan2
